Surgical pathology report (de-identified scan), TCGA case TCGA-59-2348, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Roswell Park, specimen TCGA-59-2348-01A (Primary Tumor).

[page 1 of 4]
CLINICAL HISTORY:

Date:

TCGA-59-2348

Does the patient have:	Yes	No	Unknown
Hepatitis			
TB			X
Previous biopsy			X
Previous chemotherapy			X
Previous radiation			X

PRE-OPERATIVE DIAGNOSIS AND DIFFERENTIAL:
Abdominal tumor-poorly differentiated

POST-OPERATIVE DIAGNOSIS:

SPECIFIC QUESTIONS TO BE ANSWERED BY CONSULTATION(if any):

OPERATION:

SPECIMEN:

- #1 abdominal scar
- #2 pericolic fat
- #3 omentum, spleen, transverse colon with tumor
- #4 left tube and ovary
- #5 right tube and ovary
- #6 right pelvic wall tumor
- #7 tumor from bladder peritoneum
- #8 free floating tumor left pelvic side wall

FROZEN SECTION DIAGNOSIS BY DR. PENETRANTE

FS3: poorly differentiated adenocarcinoma compatible with metastasis from ovarian primary

FS4: poorly differentiated adenocarcinoma

GROSS DESCRIPTION:

- #1 Received is an ellipse of skin measuring 6x0.6cm. Representative section submitted in one cassette.
- #2 Received are two pieces of tissue. One is a fibroadipose tissue measuring 7x3.5x0.5cm. and the other is a tan white tissue measuring 6x2.5x0.5cm. Representative section from the fibroadipose tissue is submitted in 2F and representative section from white nodular tissue is submitted in 2T.

[page 2 of 4]
Chart No: Control No:

#3 Received is an en bloc resected specimen which consists of transverse colon with attached omentum and spleen. The entire specimen weighs 3411gm. The resected portion of the transverse colon measures 44cm. in length and has a diameter of 8cm. Grossly, the mucosa of the transverse colon looks unremarkable. The serosa is adherent to the multinodular tumor in the omentum (see below).

The attached omentum measures approximately 74cm. in length. About 36cm. of the proximal omentum is replaced by yellowish white large multinodules which are matted together. The widest portion of the tumor measures 25cm. The tumor shows focal areas of hemorrhage and necrosis. The remaining portion of the omentum (about 38cm.) shows similar but slightly smaller matted nodules. These nodules extend all the way up to the hilum of the spleen. Few lymph nodes are also identified. The spleen weighs 160gm. At the hilum of the spleen there is nodular tumor measuring 4.4x1.2x0.3cm. Grossly, the tumor invades the capsule and the parenchyma to a depth of 0.5cm. The rest of the splenic parenchyma is grossly unremarkable. Representative sections of tumor frozen as FS3. Multiple sections are taken and submitted as follows: T1 to T4-sections from the tumor; A1-distal transverse colon; A2-proximal transverse colon; A3 and A4-transverse colon and adjacent tumor; L1 to L3-lymph nodes; C1 and C2-sections from the spleen with the hilar mass; C3-random section from the spleen.

#4 Received is a fallopian tube with attached mesosalpinx and ovary. The specimen weighs 46gm. The fallopian tube measures 4.5cm. in length with an external diameter of 1.0cm. No normal ovarian tissue is identified. Instead there is a tan yellow multinodular tumor near the ampulla of the fallopian tube and measures 4.5x1.3x1.5cm. There is another similar tumor near the isthmus of the fallopian tube measuring 5x3.5x2.5cm. Representative sections frozen. Multiple sections are taken and submitted as follows: T1 to T3-sections from the ampulla and the underlying tumor; T4 to T6-sections from the tumor near the isthmus; F1 to F3-random sections from the tube.

#5 Received is a fallopian tube with attached ovary and mesosalpinx. The fallopian tube measures 4cm. in length and 0.4cm. in external diameter. The ovary measures 2x1x0.5cm. On the mesosalpinx multiple yellowish white nodules identified, the largest measuring 2.5x1.5x1cm. Multiple sections are taken and submitted as follows: F1-representative sections of fallopian tube; O1 and O2-representative sections of ovary; T1 and T2-representative section from the nodule.

[page 3 of 4]
Chart No: . Control No:

#6 Received is a tan white fibroadipose tissue with matted irregular nodules in it measuring 6x4x1cm. in dimensions. Representative sections submitted in two cassettes.

#7 Received is a tan white nodular tissue measuring 2x1x0.5cm. Representative section submitted in one cassette.

#8 Received is a tan pink multinodular tissue measuring 1.4x1.2x0.4cm. Representative section submitted in one cassette.

DIAGNOSIS:

- 1) ABDOMINAL SCAR: HYPERTROPHIC SCAR; NO TUMOR SEEN
- 2) PERICOLIC FAT: METASTATIC MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA
- 3) OMENTUM, SPLEEN, TRANSVERSE COLON RESECTION: METASTATIC MODERATE TO POORLY DIFFERENTIATED ADENOCARCINOMA WITH FOCAL PAPILLARY FEATURES INVOLVING TRANSVERSE COLON, OMENTUM AND SPLEEN
- 4) LEFT TUBE AND OVARY: SEROUS PAPILLARY ADENOCARCINOMA, GRADE 2, WITH PSAMMOMA BODIES AND FOCAL CLEAR CELL AREAS INVOLVING LEFT OVARY AND MESOSALPINX, SEE NOTE
- 5) RIGHT TUBE AND OVARY: MODERATELY DIFFERENTIATED ADENOCARCINOMA WITH CLEAR CELL FEATURES INVOLVING MESOSALPINX, SEE NOTE
- 6) RIGHT PELVIC WALL TUMOR: METASTATIC MODERATELY DIFFERENTIATED ADENOCARCINOMA
- 7) BLADDER PERITONEUM, BIOPSY: METASTATIC MODERATELY DIFFERENTIATED ADENOCARCINOMA
- 8) FREE FLOATING TUMOR LEFT PELVIC SIDE WALL: METASTATIC MODERATELY DIFFERENTIATED ADENOCARCINOMA

NOTE: The tumor is a moderate to poorly differentiated adenocarcinoma with papillary, solid and clear cell features. Multiple psammoma bodies are also present. The left ovary is replaced by the tumor and measures 4.5cm. in greatest dimension. Although a primary left

[page 4 of 4]
Chart No:

Control No:

~~██████████~~

~~██████████~~5

ovarian carcinoma is favored, a primary peritoneal tumor with secondary involvement of the ovary cannot be ruled out.

Source: NCI Genomic Data Commons file f85130f1-acf9-40b2-8d3b-ab5534107969 (TCGA-59-2348.FFB300E9-CB06-4162-A751-F079FEC57153.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).